Somatic mutation profile of tumor specimen ALCH-B3IY-TTP1-A (aliquot ALCH-B3IY-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3IY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.3 years (27,495 days).
Specimen ALCH-B3IY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77322beb-1cc9-44a5-863f-fca01a2aa0d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3IY-NB1-A (Blood Derived Normal), aliquot ALCH-B3IY-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bda941d2-a92f-44ca-9459-ef936edb6257

The open-access MAF lists 134 somatic variants for this specimen: 89 protein-altering or splice-affecting, 27 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 27, Intron 9, Nonsense Mutation 9, Splice Site 5, RNA 3, 3'Flank 2, 5'UTR 2, 5'Flank 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 55/166 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABRA | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs145381419, COSV61732723; called by muse, mutect2, varscan2
- ADGRD2 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186395322, COSV58340107; called by muse, varscan2
- AFF4 | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.12); catalogued as COSV54796497; called by muse, mutect2, varscan2
- ALPK3 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369383271; called by muse, mutect2, varscan2
- AMY2B | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63716840; called by muse, mutect2, varscan2
- ASXL3 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 22/177 reads (12%) | catalogued as rs1302254196, COSV99325465; called by muse, mutect2, varscan2
- ATM | c.5879T>A p.I1960N | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs587782503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.8671G>C p.G2891R | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53756637, COSV53765757; called by muse, mutect2, varscan2
- BRSK2 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV57543254, COSV57549269; called by muse, mutect2, varscan2
- CA10 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368512398; called by muse, mutect2, varscan2
- CACNA1F | c.1959G>A p.M653I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.954); catalogued as rs1557109128, COSV59906950; called by muse, mutect2, varscan2
- CCDC74A | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs1193683975; called by muse, mutect2, varscan2
- CCNB3 | c.3973G>C p.E1325Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV52072323; called by muse, mutect2
- CNTNAP2 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241987279, COSV100672872, COSV62264200; called by muse, mutect2
- FAM47B | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1397238164, COSV61452660; called by muse, mutect2
- FGF13 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1477376621, COSV59544138; called by muse, mutect2
- IZUMO1R | c.440G>A p.R147H (on ENST00000440961; = p.R154H on NM_001199206.3) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368760432, COSV60623714; called by muse, mutect2, varscan2
- KANSL1L | c.2162G>C p.R721T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV55990463; called by muse, mutect2, varscan2
- KCNH3 | c.158C>G p.T53R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99235204; called by muse, mutect2, varscan2
- NLRP1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs200634854; called by mutect2, varscan2
- NPAS3 | c.748C>T p.P250S (on ENST00000356141 / NM_001164749.2; = p.P218S on NM_022123.3) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs1326898920; called by muse, mutect2, varscan2
- PCDHA4 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV63541201; called by muse, mutect2
- PPFIA4 | c.2131G>C p.E711Q (on ENST00000447715; = p.E712Q on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV99690156; called by muse, mutect2, varscan2
- PTGIS | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs765709407, COSV99721325; called by muse, mutect2, varscan2
- RUFY1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs899224527; called by muse, mutect2
- RUNX1 | c.425G>A p.R142K (on ENST00000344691 / NM_001001890.3; = p.R169K on NM_001754.5) | Missense Mutation (SNP) | VAF 46/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55870785; called by muse, mutect2, varscan2
- SART3 | c.1651C>T p.R551W (on ENST00000228284; = p.R533W on NM_014706.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759767239; called by muse, mutect2, varscan2
- SEMA6C | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as rs761473486, COSV58999868; called by muse, mutect2
- SMARCD1 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV101202989; called by muse, mutect2
- SNX19 | c.1915-1G>C p.X639_splice | Splice Site (SNP) | VAF 5/99 reads (5%) | catalogued as COSV56285666; called by muse, mutect2
- SSH3 | c.1386C>G p.I462M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100354667; called by mutect2, varscan2
- SYTL2 | c.1994C>G p.S665* (on ENST00000528231 / NM_001162951.2; = p.S641* on NM_032943.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV60356465; called by muse, mutect2
- UBC | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV60060306; called by muse, varscan2
- ZFHX3 | c.9319C>T p.Q3107* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV51714367; called by muse, mutect2
- ZFHX4 | c.4057G>C p.E1353Q | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as rs1277063132; called by muse, mutect2
- ZNF521 | c.2485C>T p.R829* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV64131138; called by mutect2, varscan2
- ABCA3 | c.4299G>C p.E1433D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, varscan2
- ACSM6 | c.963C>A p.Y321* | Nonsense Mutation (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- AKR1B10 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- ANKS1B | c.2420-4A>T | Splice Region (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- ARVCF | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATP6V1A | c.1016A>G p.D339G | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AUTS2 | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.286); called by muse, mutect2
- CASP8AP2 | c.5524C>G p.L1842V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.191); called by muse, varscan2
- CCDC93 | c.658-1G>A p.X220_splice | Splice Site (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- CCN1 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- CENPN | c.633+1G>C p.X211_splice | Splice Site (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- CEP41 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2
- CHST9 | c.362T>C p.L121S | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CLIC2 | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBB1 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTSH | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DCTN2 | c.483dup p.A162Cfs*14 (on ENST00000548249 / NM_001261413.2; = p.A167Cfs*14 on NM_006400.4) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- DNHD1 | c.8182G>C p.E2728Q | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2
- EPS8 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 27/280 reads (10%) | called by muse, mutect2
- EYS | c.3217A>G p.S1073G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBN1 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- FRG2C | c.554A>G p.E185G | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GABRA2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2
- GLUD2 | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH11 | c.126-1G>C p.X42_splice (on ENST00000409774; = p.X20_splice on NM_174931.4 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2
- GPRASP2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- HECTD1 | c.2629C>G p.Q877E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2
- HSPA4L | c.252G>C p.R84S | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.371); called by muse, mutect2
- IFT172 | c.4273G>A p.G1425S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ILK | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JMJD6 | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNT1 | c.3552G>C p.R1184S (on ENST00000488444; = p.R1189S on NM_020822.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- KLHL13 | c.954C>G p.Y318* | Nonsense Mutation (SNP) | VAF 19/176 reads (11%) | called by muse, mutect2, varscan2
- LAMP1 | c.1232A>T p.H411L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- LMOD1 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2
- LRRK2 | c.706+1G>C p.X236_splice | Splice Site (SNP) | VAF 17/249 reads (7%) | called by muse, mutect2
- LYST | c.1318C>G p.H440D | Missense Mutation (SNP) | VAF 37/418 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- MRPS18B | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTO1 | c.1951C>G p.H651D (on ENST00000370300 / NM_133645.3; = p.H626D on NM_012123.4) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- MUC5AC | c.15653C>T p.A5218V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.701); called by muse, varscan2
- OR5B17 | c.185G>C p.S62T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PAGE4 | c.6T>A p.S2R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDHB2 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2
- PDZD4 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROCK1 | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDC3 | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TBC1D31 | c.855T>G p.D285E | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, varscan2
- TLR2 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY4 | c.324G>C p.Q108H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WEE2 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- WWC2 | c.1496C>G p.S499C | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- ADGRF5 | c.1878C>T p.F626= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs1165513666; called by muse, mutect2
- C1S | c.1230G>A p.V410= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- C2orf16 | c.2634T>C p.H878= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs764386714; called by muse, mutect2, varscan2
- CACNA2D1 | c.813G>C p.L271= | Silent (SNP) | VAF 22/390 reads (6%) | called by muse, mutect2
- COL6A2 | c.2595G>A p.L865= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1474756520; ClinVar: uncertain significance; called by muse, mutect2
- COPS7A | c.738T>C p.A246= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1280617640; called by muse, mutect2
- CREM | c.600A>T p.G200= (on ENST00000429130; = p.G167= on NM_181571.3) | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- CYP1A2 | c.516G>C p.L172= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1237180124, COSV59658967; called by muse, mutect2
- DKK4 | c.162C>T p.L54= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- DMGDH | c.795C>T p.L265= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV54861651; called by muse, mutect2
- EEF1E1 | c.465C>T p.I155= | Silent (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- ERBB2 | c.3318C>T p.P1106= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1438968339; called by mutect2, varscan2
- LEPR | c.2127A>G p.A709= | Silent (SNP) | VAF 8/56 reads (14%) | called by mutect2, varscan2
- LPL | c.513G>A p.L171= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- LRP1B | c.9027G>A p.S3009= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs746525979, COSV67182630; called by muse, mutect2, varscan2
- MUC6 | c.5079C>T p.S1693= | Silent (SNP) | VAF 21/386 reads (5%) | catalogued as rs749576043; called by muse, mutect2
- MYLK4 | c.1068C>G p.L356= | Silent (SNP) | VAF 20/237 reads (8%) | catalogued as COSV99193935; called by muse, mutect2
- PHLPP1 | c.4563C>T p.I1521= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1299944592; called by muse, mutect2, varscan2
- ROS1 | c.1173C>G p.V391= | Silent (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- SLC1A3 | c.351G>A p.G117= | Silent (SNP) | VAF 55/174 reads (32%) | called by muse, mutect2, varscan2
- SLC35F3 | c.57G>A p.L19= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, varscan2
- ST3GAL3 | c.462C>T p.I154= (on ENST00000361392 / NM_174964.4; = p.I139= on NM_006279.5) | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- STAB1 | c.345C>T p.G115= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs757735631, COSV100401803; called by muse, mutect2, varscan2
- SYVN1 | c.1809C>G p.L603= (on ENST00000377190 / NM_172230.3; = p.L602= on NM_032431.3) | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- UNC79 | c.4965C>T p.G1655= (on ENST00000393151 / NM_001346218.2; = p.G1478= on NM_020818.5) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV56383788; called by muse, mutect2
- USP40 | c.1245C>G p.L415= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- XIRP2 | c.7917A>G p.K2639= (on ENST00000628543; = p.K2814= on NM_152381.6) | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851885 A>G | 3'Flank (SNP) | VAF 12/333 reads (4%) | called by muse, mutect2
- ASB10 | chr7:151187533 C>T | 5'Flank (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- B4GALT7 | c.723+30C>G | Intron (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- CREB3L2 | c.103-29373C>G | Intron (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- LINC02213 | n.82T>G | RNA (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85862T>C | Intron (SNP) | VAF 17/169 reads (10%) | called by muse, mutect2, varscan2
- MIR891A | n.31G>T | RNA (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- MTTP | c.-92A>C | 5'UTR (SNP) | VAF 42/240 reads (18%) | called by muse, mutect2, varscan2
- MVK | c.227-632C>T | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as rs1429121822; called by muse, mutect2
- OR4C3 | c.-46C>G | 5'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as COSV60586498; called by muse, mutect2
- PDHB | c.205-16C>T | Intron (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- POMZP3 | c.228-36C>G | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as rs753419382; called by muse, mutect2
- PTHLH | c.-22-253G>T | Intron (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- RHBDF2 | c.1389+36G>T | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- RN7SL759P | chr15:20568435 C>T | 5'Flank (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- TARDBP | c.543+51A>G | Intron (SNP) | VAF 22/156 reads (14%) | catalogued as rs368471780; called by muse, mutect2, varscan2
- UTS2B | chr3:191262905 G>C | 3'Flank (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- ZNF204P | n.850C>T | RNA (SNP) | VAF 8/139 reads (6%) | called by muse, mutect2
